Somatic mutation profile of tumor specimen TARGET-10-PARAFH-09A (aliquot TARGET-10-PARAFH-09A-01D) from TARGET case TARGET-10-PARAFH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,545 days).
Specimen TARGET-10-PARAFH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84bf14b2-76ce-4228-8d23-43be1ee94172.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARAFH-10A (Blood Derived Normal), aliquot TARGET-10-PARAFH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc414d7c-6345-40dd-b5a9-7a639f44da5b

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs730880472, COSV55534139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CLIP3 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs574879223; called by muse, mutect2, varscan2
- SPTBN5 | c.2149G>T p.G717W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1297647845; called by muse, mutect2
- GOLGA2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- KRT34 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SALL3 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- TRAK1 | c.940_973delinsCTCA p.A314_E325delinsLK (on ENST00000327628 / NM_001349247.2; = p.A256_E267delinsLK on NM_014965.5) | Splice Region (DEL) | VAF 33/61 reads (54%) | called by pindel, varscan2*
- GRID1 | c.474G>A p.T158= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs754580653, COSV100025333, COSV60030047; called by muse, mutect2, varscan2
- PCDH1 | c.3504C>T p.G1168= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs1270369302; called by muse, mutect2, varscan2
- SYNE1 | c.9699G>A p.L3233= (on ENST00000367255 / NM_182961.4; = p.L3240= on NM_033071.3) | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- CNKSR1 | c.1404-73G>A | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as rs924523426; called by muse, mutect2, varscan2
